Gene-level copy-number profile of tumor specimen BLGSP-71-27-00414-01A from CGCI case BLGSP-71-27-00414, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 56.5 years (20,627 days).
Specimen BLGSP-71-27-00414-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file edd9fe21-184f-4d74-aec9-4d380e647d19.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-27-00414-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,735 have no estimate.
https://portal.gdc.cancer.gov/files/ab3b5dc4-47c2-4abd-879f-08af37fb52fb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,008; copy number 2: 54,299; copy number 3: 1,574; copy number 5: 4; copy number 6: 1; copy number 15: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,500,512, 2 genes, copy number 5: AC239859.2, LINC02799.
- chr9:64,637,845–64,709,311, 2 genes, copy number 15: AL445665.1, BMS1P11.
- chr21:8,680,538–8,680,934, 1 gene, copy number 6: CR381572.2.
- chr22:18,906,028–18,914,238, 1 gene, copy number 5 (within-gene range 2–5): DGCR6.
- chr22:18,936,411–18,947,741, 1 gene, copy number 5 (within-gene range 2–5): AC007326.5.

Autosomal genes at a single copy (total copy number 1): 152. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
